CCDI case PBBVJX — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Brain.
https://portal.gdc.cancer.gov/cases/c1ac525b-189c-44a2-ab99-dfd0356c2ba8

Demographics
Sex at birth: male; Race: white.

Diagnoses (1)
1. Medulloblastoma, NOS: ICD-O-3 morphology code: 9470/3; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 8.7 years (3,191 days).

Biospecimens (3 samples)
- Sample 0DI6KK: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DI6KS: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DI6L3: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
